Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A39O, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A39O-01A (Primary Tumor).

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

1. THYROID AND DELPHIAN LYMPH NODES (TOTAL THYROIDECTOMY AND LYMPHADENECTOMY):

TUMOR SITE AND SIZE:

Two tumor nodules are present:

- Isthmus - 1.6 cm,
- Right lobe - 0.6 cm.

ICD-0-3

carcinoma, papillary tall cell 8344/3

Site: thyroid, NOS C13.9

hw
9/14/11

HISTOLOGIC TYPE:

Papillary carcinoma with tall cell features

LYMPH NODES:

Four (4) lymph nodes are negative for tumor (lymph nodes are surgically designated as "Delphian").

EXTENT OF INVASION (STAGING)

PRIMARY TUMOR:

pT1: Tumor size < 2 cm limited to thyroid.

REGIONAL LYMPH NODES:

pN0: No regional lymph node metastasis (based on four Delphian lymph nodes)

DISTANT METASTASIS:

pMx: Cannot be assessed.

MARGINS:

Margins uninvolved.

Carcinoma is 1 mm from the nearest soft tissue margin.

VENOUS/LYMPHATIC INVASION:

Absent

NOTE: Dr. _____ agrees with the diagnosis. This case was shown at the

Source: NCI Genomic Data Commons file 1e7161e4-0134-4efa-a0e2-008e097b6fb6 (TCGA-ET-A39O.95EB9A3F-F213-4D62-9823-21E3D31DDB5E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).